Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A2N0, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A2N0-01A (Primary Tumor).

IHFA Discrepancy		✓
From Malignancy History		✓
		for 8/18/11

SPECIMEN TAKEN

FINAL DIAGNOSIS -----

THYROID, RIGHT (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

ICD-O-3

TUMOR SITE:

Right lobe

carcinoma, papillary, thyroid 8260/3

Site: thyroid, Nos C73.9

for

8/18/11

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE:

Greatest dimension: 2.0 cm

FOCALITY:

Unifocal

LYMPH NODES:

Metastatic carcinoma in 20 of 27 lymph nodes

EXTENT OF INVASION

PRIMARY TUMOR:

pT1b: Tumor >1 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Absent

NOTE: Histologically unremarkable parathyroid gland identified left inferior.

Source: NCI Genomic Data Commons file 7a37081a-2525-4824-a2e3-5cf1250f0f61 (TCGA-ET-A2N0.32489588-DB83-48DF-A0A9-9D3669D5511C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).